CCDI case PBCLWK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/2e3f97eb-ac7e-4d95-a1a7-bf6b12ba3945

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Carcinoma, undifferentiated, NOS: ICD-O-3 morphology code: 8020/3; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 16.6 years (6,064 days).

Biospecimens (3 samples)
- Sample 0DVBVE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVBVN: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVBVR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
